Somatic mutation profile of tumor specimen TCGA-EK-A2RB-01A (aliquot TCGA-EK-A2RB-01A-11D-A18J-09) from TCGA case TCGA-EK-A2RB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 48.6 years (17,752 days).
Specimen TCGA-EK-A2RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb357106-ae4e-4e68-9042-2b86124eb64f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RB-10A (Blood Derived Normal), aliquot TCGA-EK-A2RB-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5632b2bc-994d-47ba-9434-7e53cc7bd96b

The open-access MAF lists 121 somatic variants for this specimen: 88 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 31, Nonsense Mutation 6, Splice Region 2, Frame Shift Del 2, In Frame Del 2, Splice Site 1, 3'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LRP6 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.586); catalogued as rs121918313, CM070983, COSV53793011; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as rs143566631; called by muse, mutect2, varscan2
- ADAMTS14 | c.3409C>A p.P1137T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV64605763; called by muse, mutect2, varscan2
- ADGRL1 | c.3283G>A p.V1095I (on ENST00000340736 / NM_001008701.3; = p.V1090I on NM_014921.5) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs536482945, COSV61566268; called by muse, mutect2, varscan2
- ARMH4 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs761546306, COSV50771714, COSV50778649; called by muse, mutect2, varscan2
- ARPP21 | c.591G>C p.M197I | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51806684; called by muse, mutect2, varscan2
- BAP1 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 11/18 reads (61%) | catalogued as COSV56230643; called by muse, mutect2, varscan2
- BICD1 | c.1958G>C p.R653T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV55686797; called by muse, mutect2, varscan2
- CCDC22 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66051789; called by muse, mutect2, varscan2
- CD99 | c.195C>T p.D65= | Splice Region (SNP) | VAF 66/175 reads (38%) | catalogued as rs146608942, COSV66991529; called by muse, mutect2, varscan2
- CDH5 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.826); catalogued as rs755386476, COSV58519548; called by muse, mutect2, varscan2
- CFAP52 | c.60C>G p.I20M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV60494786; called by muse, mutect2, varscan2
- CLDN16 | c.60G>T p.L20F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759868163, COSV53229126; called by muse, mutect2, varscan2
- COL26A1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746391883, COSV58125966; called by muse, mutect2, varscan2
- CRACR2B | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs1300195939, COSV58990863; called by muse, mutect2, varscan2
- CWC22 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV55431827; called by muse, mutect2, varscan2
- DCAF4L2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.061); catalogued as rs1368798705, COSV60476907, COSV60478339; called by muse, mutect2, varscan2
- DOCK11 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as COSV52246541; called by muse, mutect2, varscan2
- DOCK11 | c.2654A>T p.E885V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV52246550; called by muse, mutect2
- DSCAM | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as rs762902524, COSV68021000, COSV68034391; called by muse, mutect2, varscan2
- EIF2AK1 | c.277+1G>A p.X93_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as rs148495208; called by muse, mutect2, varscan2
- ERF | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.014); catalogued as COSV55897251; called by muse, mutect2, varscan2
- ERI3 | c.609C>T p.L203= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as COSV64833329; called by muse, mutect2, varscan2
- EVPL | c.2569_2571del p.E857del | In Frame Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs1405569366; called by mutect2, pindel, varscan2
- FAH | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143243347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL18 | c.922C>A p.L308M | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV66668323; called by muse, mutect2, varscan2
- GPER1 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV52470431; called by muse, mutect2, varscan2
- H3-3A | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV64733602; called by muse, mutect2, varscan2
- HGF | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55946855, COSV55955573; called by muse, mutect2, varscan2
- HMCN1 | c.2605G>T p.A869S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54934301; called by muse, varscan2
- HOXD11 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV50912805; called by muse, mutect2, varscan2
- ICE1 | c.5653G>A p.E1885K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV56831026; called by muse, mutect2, varscan2
- IDS | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61714125; called by muse, mutect2, varscan2
- IGKV5-2 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs745660051; called by muse, mutect2, varscan2
- IQCA1 | c.418C>G p.Q140E | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs773736427, COSV104392732, COSV99609926, COSV99610413; called by muse, mutect2, varscan2
- JAKMIP3 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148025571; called by muse, mutect2, varscan2
- KCNV1 | c.1066G>T p.G356* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV52088664; called by muse, mutect2, varscan2
- KIF22 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs780221407, COSV50717771; called by muse, mutect2, varscan2
- KMT2C | c.1094A>G p.H365R | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV100076486; called by muse, mutect2
- LATS1 | c.2810G>T p.G937V | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53598423; called by muse, mutect2, varscan2
- LMTK3 | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs771558775, COSV54316501; called by muse, mutect2, varscan2
- MAP2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); catalogued as rs1325438733, COSV52305184; called by muse, mutect2
- MDN1 | c.11249C>T p.A3750V | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs772321751, COSV65524411; called by muse, mutect2, varscan2
- MYO15A | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.401); catalogued as rs777527625, COSV52753801; called by muse, mutect2, varscan2
- NKAPL | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as COSV59199043; called by muse, mutect2
- NUBP2 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51908107; called by muse, mutect2, varscan2
- OBSCN | c.8119G>A p.D2707N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.073); catalogued as COSV52819373; called by muse, mutect2, varscan2
- OR8K1 | c.71C>A p.T24K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs895669608, COSV54404248, COSV99687584; called by muse, varscan2
- OTC | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV50003034, COSV50004056; called by muse, mutect2, varscan2
- PCDHB7 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs782318542, COSV50756029; called by muse, mutect2
- PCDHGA2 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.033); catalogued as rs746420859, COSV54006428, COSV54036882; called by muse, mutect2, varscan2
- PLPP4 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV64829438; called by muse, mutect2, varscan2
- PLPPR5 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768912067, COSV54177733; called by muse, mutect2, varscan2
- PPP4R3B | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV55408494; called by muse, mutect2, varscan2
- RASSF7 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV60348333; called by muse, mutect2, varscan2
- RPS7 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV100514017; called by muse, mutect2
- RTN1 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV50743411; called by muse, mutect2, varscan2
- RTN4RL1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs572459222, COSV58677687; called by muse, mutect2, varscan2
- SAMD4A | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs781289174, COSV51887034; called by muse, mutect2, varscan2
- SCP2 | c.153G>C p.Q51H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV65262288; called by muse, mutect2, varscan2
- SCRN2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1448557007, COSV51637131; called by muse, mutect2, varscan2
- SFTPD | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs149865718; called by muse, mutect2, varscan2
- SH3TC1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs766716993, COSV55285873; called by muse, mutect2, varscan2
- SLC36A2 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58864800; called by muse, mutect2, varscan2
- SREBF1 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1274094351, COSV55419441; called by muse, mutect2, varscan2
- SUV39H1 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61921280; called by muse, mutect2, varscan2
- TANC1 | c.1649G>A p.S550N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV55095312; called by muse, mutect2, varscan2
- TBC1D8B | c.3016G>C p.D1006H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as COSV52182796; called by muse, mutect2, varscan2
- TMEM144 | c.368C>G p.S123* | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | catalogued as COSV56700338; called by muse, mutect2, varscan2
- TRIOBP | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1346236077, COSV60374773; called by muse, mutect2, varscan2
- TSPEAR | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs370848096, COSV59958847; called by muse, mutect2, varscan2
- TSTD2 | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV52246720, COSV52251909; called by muse, mutect2, varscan2
- TTN | c.58717G>A p.D19573N (on ENST00000591111; = p.D12149N on NM_003319.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | PolyPhen probably damaging (0.998); catalogued as rs746677565, COSV60036438, COSV60294198; called by muse, mutect2, varscan2
- TUSC1 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.696); catalogued as COSV63662116; called by muse, mutect2, varscan2
- UBA2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV55830088; called by muse, mutect2, varscan2
- USP51 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV72351912; called by muse, mutect2, varscan2
- VCAN | c.3923C>G p.S1308C | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54112473; called by muse, mutect2
- WDR7 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV54361606, COSV99589213; called by muse, mutect2, varscan2
- ZBTB16 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV60098669; called by muse, mutect2, varscan2
- ZC3H7B | c.2435G>A p.G812E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.06); catalogued as COSV60964343; called by muse, mutect2, varscan2
- ZKSCAN5 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs1443311443, COSV58744312; called by muse, mutect2, varscan2
- ZNF234 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as rs537418600, COSV70603118; called by muse, mutect2, varscan2
- ZNF85 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs775876637, COSV60216846; called by muse, mutect2, varscan2
- IQGAP2 | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2
- PATZ1 | c.1202dup p.H401Qfs*6 | Frame Shift Ins (INS) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- PDZD8 | c.2913_2914del p.P972Qfs*9 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | called by pindel, varscan2
- PPIL2 | c.845_853del p.V282_H285delinsD | In Frame Del (DEL) | VAF 38/85 reads (45%) | called by mutect2, pindel, varscan2
- A2ML1 | c.426C>T p.V142= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as COSV55297276; called by muse, mutect2, varscan2
- AQP11 | c.468G>A p.K156= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV57993101; called by muse, mutect2, varscan2
- CBX1 | c.465G>A p.K155= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as COSV56682664; called by muse, mutect2, varscan2
- CENPI | c.222G>A p.E74= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV54505697; called by muse, mutect2, varscan2
- DHRS12 | c.720G>A p.A240= (on ENST00000444610 / NM_001377930.1; = p.A191= on NM_024705.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV54472559; called by muse, mutect2
- DHX38 | c.1914C>T p.L638= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV51700505; called by muse, mutect2, varscan2
- FCRL2 | c.912C>T p.L304= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV63834101, COSV63834946; called by muse, mutect2, varscan2
- FRAS1 | c.1476C>T p.H492= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs373093881; called by muse, mutect2, varscan2
- FSTL5 | c.2007C>T p.S669= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV60196021, COSV60223489; called by muse, mutect2, varscan2
- GFI1B | c.792G>A p.K264= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV59746706; called by muse, mutect2, varscan2
- GUCA1A | c.312C>T p.N104= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs749013749, CM085455, COSV50003573; called by muse, mutect2, varscan2
- MAP3K6 | c.2346C>T p.F782= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100709452; called by muse, mutect2, varscan2
- MYO1C | c.1347C>T p.F449= (on ENST00000648651 / NM_001080779.2; = p.F414= on NM_033375.5) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV63000442; called by muse, mutect2, varscan2
- OR10J1 | c.438G>T p.L146= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV71129495; called by muse, mutect2, varscan2
- OR5AP2 | c.693C>A p.V231= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV57258627; called by muse, mutect2, varscan2
- OR8K1 | c.124C>T p.L42= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs756021105, COSV54404263; called by muse, varscan2
- OSBPL5 | c.417G>A p.L139= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99720793; called by muse, mutect2, varscan2
- PCDHA6 | c.1443C>T p.D481= | Silent (SNP) | VAF 76/210 reads (36%) | catalogued as rs550072556, COSV65344169; called by muse, mutect2, varscan2
- PRKCB | c.1947C>T p.I649= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV57797252; called by muse, mutect2, varscan2
- RP1 | c.2409T>A p.P803= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV55124906; called by muse, mutect2
- SCN4A | c.4053G>A p.T1351= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs376395544; called by muse, mutect2, varscan2
- SEMA7A | c.1347C>T p.F449= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs376016282; called by muse, mutect2, varscan2
- SNED1 | c.1956G>A p.R652= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs369648878, COSV60032324; called by muse, mutect2, varscan2
- SYNE1 | c.14565G>A p.R4855= (on ENST00000367255 / NM_182961.4; = p.R4784= on NM_033071.3) | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as rs1237053788, COSV55079772; called by muse, mutect2, varscan2
- TRIM67 | c.105G>A p.A35= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV64160203; called by muse, mutect2, varscan2
- TRIM72 | c.1263C>T p.D421= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs753097453, COSV59069784; called by muse, mutect2, varscan2
- VPS13D | c.8031G>A p.A2677= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs147189508; called by muse, mutect2, varscan2
- VPS16 | c.1143G>A p.Q381= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs748294859, COSV66798660; called by muse, mutect2, varscan2
- ZNF185 | c.1056C>T p.S352= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV100248667; called by muse, mutect2
- ZNF257 | c.459C>G p.V153= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV71311198; called by muse, mutect2, varscan2
- ZNF548 | c.1224C>T p.L408= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs766938735, COSV60241835; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.*152C>A | 3'UTR (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52536487; called by muse, mutect2, varscan2
- USP6 | c.1079-127T>C | Intron (SNP) | VAF 22/71 reads (31%) | catalogued as COSV51494227; called by muse, mutect2, varscan2
